Somatic mutation profile of tumor specimen 0DG87U from CCDI case PBBTAK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 0.8 years (287 days).
Specimen 0DG87U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21075e36-9456-4a76-a099-591fb1a90bfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86fe60d3-42fb-4cdb-98f4-9191d3961de7

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 461/557 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FRMPD3 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 158/668 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1427432277, COSV99345741, COSV99345833; called by muse, mutect2, varscan2
- OR2M2 | c.447G>C p.W149C | Missense Mutation (SNP) | VAF 165/930 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USH2A | c.6676T>C p.C2226R | Missense Mutation (SNP) | VAF 185/663 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HS6ST2 | c.618C>G p.P206= | Silent (SNP) | VAF 20/390 reads (5%) | called by muse, mutect2
- DUSP22 | c.435+89G>A | Intron (SNP) | VAF 10/158 reads (6%) | catalogued as rs1160886600; called by muse, mutect2
